Somatic mutation profile of tumor specimen TCGA-3B-A9HI-01A (aliquot TCGA-3B-A9HI-01A-11D-A387-09) from TCGA case TCGA-3B-A9HI, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 68.4 years (24,984 days).
Specimen TCGA-3B-A9HI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d60d50c1-8740-4539-ae39-e573be2ec91d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HI-10A (Blood Derived Normal), aliquot TCGA-3B-A9HI-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42f1696d-d6e4-4b72-990b-8f33a6fb375c

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Frame Shift Del 5, Nonsense Mutation 2, RNA 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGGF1 | c.656A>G p.H219R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100461639; called by muse, mutect2, varscan2
- ATRX | c.2482del p.M828* | Frame Shift Del (DEL) | VAF 55/91 reads (60%) | catalogued as COSV100971467; called by mutect2, pindel, varscan2
- CCDC146 | c.2052G>A p.M684I | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99592322; called by muse, mutect2, varscan2
- CHAF1A | c.1913A>G p.H638R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100010974; called by muse, mutect2, varscan2
- COL18A1 | c.4159C>A p.P1387T (on ENST00000359759 / NM_130444.3; = p.P1152T on NM_030582.4) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs973622095, COSV100645069; called by muse, mutect2, varscan2
- COL28A1 | c.333G>C p.W111C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101258417, COSV68081941; called by muse, mutect2, varscan2
- DYM | c.553T>G p.C185G | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs774272903, COSV99492788; called by muse, mutect2, varscan2
- ERGIC1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1173451115, COSV67126976; called by muse, mutect2, varscan2
- HAVCR1 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100208071; called by muse, mutect2, varscan2
- IGFALS | c.1685T>C p.V562A | Missense Mutation (SNP) | VAF 105/340 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs766957939, COSV99236414; called by muse, mutect2, varscan2
- KPNB1 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747385025, COSV99267937; called by muse, mutect2, varscan2
- OBSCN | c.4643C>T p.A1548V | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs768433647, COSV99475114; called by muse, mutect2, varscan2
- OR56A3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV100290092; called by muse, mutect2, varscan2
- PCSK9 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100135013; called by muse, mutect2, varscan2
- POLD1 | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV101486802; called by muse, mutect2, varscan2
- PRKCG | c.1799C>A p.S600* | Nonsense Mutation (SNP) | VAF 12/105 reads (11%) | catalogued as COSV99668695, COSV99669099; called by muse, mutect2, varscan2
- RARB | c.242C>G p.P81R (on ENST00000383772 / NM_001290216.2; = p.P74R on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as COSV100412177, COSV100412211; called by muse, mutect2, varscan2
- RARS1 | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.483); catalogued as rs766375022, COSV99199066; called by muse, mutect2, varscan2
- RASGEF1C | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100745742; called by muse, mutect2, varscan2
- REN | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV99689457; called by muse, mutect2, varscan2
- SLC17A6 | c.977T>C p.F326S | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99581060; called by muse, mutect2, varscan2
- SLC9A3 | c.1352T>A p.F451Y | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV99375768; called by muse, mutect2, varscan2
- SUCO | c.2798G>T p.G933V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1430036638, COSV99742276; called by muse, mutect2
- TMC2 | c.1413G>T p.E471D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100727420; called by muse, mutect2
- TUBGCP3 | c.2443A>T p.I815F | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99996646; called by muse, mutect2, varscan2
- XIRP2 | c.6505C>T p.L2169F (on ENST00000628543; = p.L2344F on NM_152381.6) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.061); catalogued as COSV99740301; called by muse, mutect2, varscan2
- ZNF391 | c.1009G>T p.D337Y | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV55124444; called by muse, mutect2
- ZNF467 | c.1612A>G p.T538A | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs1468437627, COSV100117844; called by muse, mutect2, varscan2
- BTN3A3 | c.201_202del p.W67Cfs*53 | Frame Shift Del (DEL) | VAF 29/204 reads (14%) | called by mutect2, pindel, varscan2
- FBXO3 | c.743G>A p.W248* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- NOL6 | c.481_484del p.T161Lfs*21 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- RSBN1 | c.2350del p.S784Vfs*29 | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | called by mutect2, pindel, varscan2
- TGS1 | c.530_531del p.T177Rfs*8 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- ALAS2 | c.729G>T p.L243= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100238104; called by muse, mutect2, varscan2
- CHD9 | c.1179A>G p.Q393= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as COSV101271990; called by muse, mutect2, varscan2
- CHST8 | c.1188G>A p.S396= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs777311622, COSV99380863; called by muse, mutect2, varscan2
- DGCR2 | c.216G>A p.E72= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV99593414; called by muse, mutect2, varscan2
- LAPTM5 | c.531G>A p.E177= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs1270149342, COSV99612250; called by muse, mutect2, varscan2
- LHX1 | c.897C>T p.G299= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs546566090; called by muse, mutect2, varscan2
- MEF2B | c.168G>A p.Q56= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV99364416; called by muse, mutect2, varscan2
- POM121L12 | c.594C>T p.F198= | Silent (SNP) | VAF 31/216 reads (14%) | catalogued as rs1398358196, COSV68692268; called by muse, mutect2, varscan2
- SCAMP5 | c.117C>T p.R39= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100723800; called by muse, mutect2, varscan2
- SYNE2 | c.1416C>T p.N472= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs1467908946, COSV100647114; called by muse, mutect2, varscan2
- HERC2P3 | n.2235A>G | RNA (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20397430 del AGTATGAATTGTCTTAT | 3'Flank (DEL) | VAF 42/160 reads (26%) | called by mutect2, pindel, varscan2
- SGTA | c.-14_-3del | 5'UTR (DEL) | VAF 29/116 reads (25%) | called by mutect2, pindel, varscan2
